Somatic mutation profile of tumor specimen 0DRXED from CCDI case PBCHEX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.1 years (3,309 days).
Specimen 0DRXED: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3400b727-08e3-440e-987c-f63f365f0db7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRXET (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/34d1a7fa-d7bb-410e-8504-f95162f1645d

The open-access MAF lists 9 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 3, Missense Mutation 3, 3'UTR 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HSD3B7 | c.694+6G>C | Splice Region (SNP) | VAF 8/291 reads (3%) | called by muse, mutect2
- RASSF9 | c.890A>T p.D297V | Missense Mutation (SNP) | VAF 68/567 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- TCP11L1 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 218/358 reads (61%) | SIFT deleterious (0.04); PolyPhen benign (0.108); called by muse, mutect2
- USP17L2 | c.505G>C p.V169L | Missense Mutation (SNP) | VAF 26/364 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2
- ACSM4 | c.759C>T p.C253= | Silent (SNP) | VAF 30/470 reads (6%) | catalogued as rs200562081; called by muse, mutect2
- ADGRL2 | c.183C>T p.S61= | Silent (SNP) | VAF 102/286 reads (36%) | catalogued as rs769350694; called by muse, mutect2, varscan2
- HSD3B7 | c.525G>A p.G175= | Silent (SNP) | VAF 12/332 reads (4%) | called by muse, mutect2
- HSD3B7 | c.431+29G>C | Intron (SNP) | VAF 20/232 reads (9%) | called by muse, mutect2
- LRRIQ1 | c.*64A>G | 3'UTR (SNP) | VAF 70/106 reads (66%) | called by muse, mutect2, varscan2
